Somatic mutation profile of tumor specimen 0DU818 from CCDI case PBCKJA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Infantile fibrosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.2 years (83 days).
Specimen 0DU818: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02db28ac-ca7d-4525-a4e8-b603fbbe87fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU808 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a1849b9-a687-4aee-9f55-8ff0d7667906

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 482/1592 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs760536500, COSV55529040; called by muse, mutect2, varscan2
- KCND3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 80/1583 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as COSV100137988; called by muse, mutect2
- OR7A17 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 150/1966 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.553); catalogued as rs756134835; called by muse, mutect2
- ABR | c.1414C>T p.L472F (on ENST00000302538 / NM_021962.5; = p.L435F on NM_001092.5) | Missense Mutation (SNP) | VAF 72/1575 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- GNB5 | c.755A>C p.N252T (on ENST00000261837 / NM_016194.4; = p.N210T on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 856/1736 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRD5A3 | c.114_124del p.L40Rfs*27 | Frame Shift Del (DEL) | VAF 530/1674 reads (32%) | called by mutect2, pindel, varscan2
